Surgical pathology report (de-identified scan), TCGA case TCGA-44-3917, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-3917-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Level 10 lymph node
- B. Right upper lobe
- C. R4 lymph node right side
- D. Level 7 lymph node right side

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass.

GROSS DESCRIPTION

A. Received unfixed labeled "level 10 lymph node" and consists of three portions of soft reddish brown tissue, the smallest measures 0.7 x 0.3 x 0.3 cm. The largest measures 1 x 0.8 x 0.5 cm. The two smaller nodes are submitted all in block 1. The largest node is bisected. On sectioning it is homogeneous, soft and reddish brown. It is bisected and is all submitted in block 2. AS-2.

B. Received fresh for tissue procurement as "right upper lobe". It consists of a lobe of lung weighing 190 grams and measuring 17 x 11.2 x 4.2 cm. There is a longitudinal staple line medially measuring 17 cm in length. The pleural surface contains a moderate amount of anthracotic pigmentation. On the inferior edge there are two adjacent dull white soft plaque-like areas which are 0.5 cm apart. Each of these flattened areas measures 0.6 cm in greatest dimension. There is also a mass palpable in the inferior portion of the specimen. Overlying pleura is smooth and glistening. On section, there is a discrete fleshy tan necrotic tumor mass measuring 3.2 x 3.2 x 3 cm. Samples are taken for tissue procurement. Tumor does not approximate pleural surfaces. A touch preparation is made and examined in order to obviate the need for flow cytometry. A second staple line is found joining the first in its mid portion. The second staple line measures 3.5 cm in length. Upon removing this shorter staple line, the bronchial margin is identified and appears normal. When probing

GROSS DESCRIPTION

this bronchus, tumor is encountered within 2 cm of the staple line. Major vessels are also stapled and appear unremarkable at their margins. Also noted in the hilar area are two adjacent, soft, blackened lymph nodes measuring up to 1.1 cm in greatest dimension.

[page 2 of 3]
BLOCK SUMMARY: 1 - Small pleural "plaques"; 2 - bronchial and vascular margins of resection; 3 - hilar nodal tissue; 4 - tumor with bronchus; 5-9 - additional tumor; 10 - random section.

C. Received fresh subsequently fixed in formalin labeled "R4 lymph node right side" is a 4 x 3.5 x 1.5 cm aggregate of brown gray tan irregular soft tissue fragments grossly consistent with lymphoid tissue. The specimens are entirely submitted in two cassettes. AS-2.

D. Received fresh subsequently fixed in formalin labeled "level 7 lymph node" are multiple red black irregular soft tissue fragments which may contain possible lymphoid tissue. This has an aggregate measurement of 4 x 3 x 1 cm. The specimens are entirely submitted in one cassette. AS-1.

MICROSCOPIC DESCRIPTION

A, C & D, microscopic examination performed.

B. This right upper lobe of lung contains a 3.2 cm poorly differentiated adenocarcinoma. All margins are negative for tumor. The tumor invades and ulcerates a major bronchus. Please see the template below:

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT): The tumor measures 3.2 cm in greatest dimension, pT2

MICROSCOPIC DESCRIPTION

Margins of resection: Bronchial and vascular margins negative for tumor.

Direct extension of tumor: None identified

Venous (large vessel) invasion: Negative

Arterial (large vessel) invasion: Negative

Lymphatic (small vessel) invasion: Negative

Regional lymph nodes (pN): Attached to the main specimen there are two lymph nodes which are negative for

metastatic

[page 3 of 3]
disease. Multiple other nodes are identified in parts A,
C & D and all are negative, pN0.
Distant metastasis (pM): Cannot be assessed
Other findings: Two nonspecific small areas of fibrosis
noted in a subpleural location.

5, 4x3, 64

DIAGNOSIS

- A. Level 10 lymph node, dissection - Three lymph nodes negative
for
metastatic disease, 0/3.
- B. Right upper lobe, lobectomy - Right upper lobe of lung with
poorly differentiated adenocarcinoma, invading and ulcerating
bronchial tissue. All margins and pleural surfaces negative
for tumor. Two additional lymph nodes present negative for
metastatic disease, 0/2.
- C. R4 lymph nodes right side, dissection - Multiple reactive lymph
nodes with anthracotic pigmentation, all negative for metastatic
disease.
- D. Level 7 lymph nodes, right side, dissection - Multiple reactive
lymph nodes with anthracotic pigmentation, all negative for
metastatic disease.

DIAGNOSIS

--- End Of Report ---

Source: NCI Genomic Data Commons file f963a845-112f-4060-9ba1-77c142b24a59 (TCGA-44-3917.240F6268-FFEF-488E-855D-9C39E3969C65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).